Somatic mutation profile of tumor specimen HCM-STAN-1111-C19-01A (aliquot HCM-STAN-1111-C19-01A-11D-A937-36) from HCMI case HCM-STAN-1111-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1.
Specimen HCM-STAN-1111-C19-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31a4168a-80ba-4589-aa3c-7444e5ced0af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-1111-C19-11A (Solid Tissue Normal), aliquot HCM-STAN-1111-C19-11A-11D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b8a5a4b-653a-4fa8-840a-cfb64b4ae090

The open-access MAF lists 82 somatic variants for this specimen: 61 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4057G>T p.E1353* | Nonsense Mutation (SNP) | VAF 493/572 reads (86%) | hotspot (GDC flag); catalogued as rs1114167568, CD972008, CM130060, COSV57321750, COSV57332693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIF1A | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 105/450 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797045164, CM157165, COSV57482306; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 282/535 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTL6B | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 136/663 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV50514422; called by muse, mutect2, varscan2
- ARL4D | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 141/651 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV60721410; called by muse, mutect2, varscan2
- AUTS2 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 162/765 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs565156541; called by muse, mutect2, varscan2
- C8orf82 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 172/853 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1349607593; called by muse, mutect2, varscan2
- CEACAM18 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 248/591 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs200987432; called by muse, mutect2, varscan2
- CELSR1 | c.3827C>T p.P1276L | Missense Mutation (SNP) | VAF 156/593 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as rs143212879, COSV53088303; called by muse, mutect2, varscan2
- CPAMD8 | c.3697C>T p.R1233C (on ENST00000651564; = p.R1186C on NM_015692.5) | Missense Mutation (SNP) | VAF 177/501 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1349978599, COSV71596903; called by muse, mutect2, varscan2
- EPHA6 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 105/399 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67557029, COSV67575552; called by muse, mutect2, varscan2
- GLIPR1L2 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 145/439 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs778332182; called by muse, mutect2, varscan2
- GRIK3 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 203/394 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.427); catalogued as rs376333303; called by muse, mutect2, varscan2
- GUSB | c.1091C>G p.P364R | Missense Mutation (SNP) | VAF 181/440 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as CM092098, COSV59222273; called by muse, mutect2, varscan2
- HEG1 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 94/324 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.304); catalogued as rs970126972; called by mutect2, varscan2
- HUWE1 | c.11911C>T p.R3971W | Missense Mutation (SNP) | VAF 212/575 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53357667; called by muse, mutect2, varscan2
- KCP | c.4307G>A p.R1436H (on ENST00000620378; = p.R1560H on NM_001366122.1) | Missense Mutation (SNP) | VAF 28/784 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as rs955455733; called by muse, mutect2
- KLHL41 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 87/342 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1033276582, COSV52930357; called by muse, mutect2, varscan2
- KRT17 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 145/371 reads (39%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); catalogued as rs754747437; called by muse, mutect2, varscan2
- KRT6B | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 283/1230 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as rs772519522; called by muse, varscan2
- LCP2 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 58/594 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs768642894, COSV50465737; called by muse, mutect2
- LMNB2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 258/666 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1410022707, COSV57591247; called by muse, mutect2, varscan2
- LRP1B | c.5570G>T p.R1857M | Missense Mutation (SNP) | VAF 71/313 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67203350; called by muse, mutect2, varscan2
- MAGEB6B | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 66/848 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs780519025, COSV69689925; called by muse, mutect2
- MARCKSL1 | c.501_503del p.E168del | In Frame Del (DEL) | VAF 127/539 reads (24%) | catalogued as rs781178665; called by pindel, varscan2
- NANOG | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 101/363 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs767551668, COSV57551872; called by muse, mutect2
- NANOGP8 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 132/1332 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1015155313; called by muse, mutect2
- PAPPA2 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 284/589 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.16); catalogued as rs867343882, COSV62781208; called by muse, mutect2, varscan2
- PGBD1 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 136/541 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.95); catalogued as rs377213554, COSV99460166; called by muse, mutect2, varscan2
- PGR | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 54/250 reads (22%) | catalogued as rs1315135533, COSV54796997; called by muse, mutect2, varscan2
- PKHD1 | c.8936G>A p.R2979Q | Missense Mutation (SNP) | VAF 144/273 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as rs761651295, COSV100581179; called by muse, mutect2, varscan2
- PRPS2 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 306/775 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV66180061; called by muse, mutect2, varscan2
- RBMXL3 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 28/1089 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.821); catalogued as rs1556556898, COSV57754903; called by muse, mutect2
- RSPH10B2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752004967; called by mutect2, varscan2
- SCN2B | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 171/343 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs774866184; called by muse, mutect2, varscan2
- UNC5C | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 203/429 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as rs376193832; called by muse, mutect2, varscan2
- UNC79 | c.4183C>T p.R1395W (on ENST00000393151 / NM_001346218.2; = p.R1218W on NM_020818.5) | Missense Mutation (SNP) | VAF 127/657 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769549721, COSV56378995; called by muse, mutect2, varscan2
- WIZ | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 19/755 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as rs1161514530; called by muse, mutect2
- ZNF415 | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 298/744 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV54706302; called by muse, mutect2
- ZNF526 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 129/736 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs141088005; called by muse, mutect2, varscan2
- ZNF761 | c.702G>C p.Q234H | Missense Mutation (SNP) | VAF 83/408 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs200154624; called by muse, mutect2, varscan2
- CASK | c.1156_1168del p.Y387Tfs*38 | Frame Shift Del (DEL) | VAF 55/424 reads (13%) | called by mutect2, pindel, varscan2
- CBLN2 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 60/361 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLASRP | c.974A>T p.K325M | Missense Mutation (SNP) | VAF 348/851 reads (41%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- DAPK1 | c.2306T>A p.L769H | Missense Mutation (SNP) | VAF 130/495 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DNAH5 | c.13557A>T p.K4519N | Missense Mutation (SNP) | VAF 274/654 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- DOCK2 | c.3393A>T p.E1131D | Missense Mutation (SNP) | VAF 173/423 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EHF | c.43_61del p.N15Rfs*68 | Frame Shift Del (DEL) | VAF 119/296 reads (40%) | called by mutect2, pindel, varscan2
- EPM2A | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 99/343 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KCNA3 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 330/606 reads (54%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- KCNQ4 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 20/677 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- NUDT7 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 87/385 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR7A10 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 209/480 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- OS9 | c.461G>A p.W154* | Nonsense Mutation (SNP) | VAF 247/481 reads (51%) | called by muse, mutect2, varscan2
- PDE10A | c.330C>A p.S110R | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); called by mutect2, varscan2
- PLEKHA4 | c.416A>G p.E139G | Missense Mutation (SNP) | VAF 274/676 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM47 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 132/744 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- TNC | c.1487G>C p.C496S | Missense Mutation (SNP) | VAF 156/620 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TOGARAM2 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 112/362 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TTC7A | c.1723C>T p.L575F | Missense Mutation (SNP) | VAF 122/523 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFYVE26 | c.4780C>A p.H1594N | Missense Mutation (SNP) | VAF 126/296 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADAMTS16 | c.3048C>A p.T1016= | Silent (SNP) | VAF 231/596 reads (39%) | called by muse, mutect2, varscan2
- ALK | c.4518G>A p.T1506= | Silent (SNP) | VAF 122/480 reads (25%) | catalogued as rs761628666, COSV66560515; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGEF10 | c.357C>T p.I119= (on ENST00000398564; = p.I95= on NM_014629.4) | Silent (SNP) | VAF 140/701 reads (20%) | catalogued as rs539543107, COSV50657613; called by muse, mutect2, varscan2
- BHLHA15 | c.93G>A p.P31= | Silent (SNP) | VAF 339/883 reads (38%) | catalogued as rs893709059; called by muse, mutect2, varscan2
- COL4A6 | c.855A>G p.G285= | Silent (SNP) | VAF 181/466 reads (39%) | catalogued as rs1206561891; called by muse, mutect2, varscan2
- DNAH17 | c.2121C>T p.N707= | Silent (SNP) | VAF 209/552 reads (38%) | catalogued as rs201170230; called by muse, mutect2, varscan2
- EFCAB6 | c.1758G>A p.Q586= | Silent (SNP) | VAF 199/404 reads (49%) | called by muse, mutect2, varscan2
- GRAMD4 | c.1440G>A p.T480= | Silent (SNP) | VAF 107/442 reads (24%) | catalogued as rs1345895870; called by muse, mutect2, varscan2
- HCN4 | c.3378C>T p.S1126= | Silent (SNP) | VAF 71/850 reads (8%) | catalogued as rs758673317; called by muse, mutect2
- NCAM1 | c.1746C>T p.Y582= (on ENST00000316851 / NM_181351.5; = p.Y572= on NM_000615.7) | Silent (SNP) | VAF 194/406 reads (48%) | catalogued as rs3741072; called by muse, mutect2, varscan2
- PCDHA13 | c.2292G>A p.P764= | Silent (SNP) | VAF 250/574 reads (44%) | catalogued as COSV56549255, COSV99169757; called by muse, mutect2, varscan2
- POM121L12 | c.267G>A p.P89= | Silent (SNP) | VAF 310/779 reads (40%) | catalogued as rs772385441, COSV101374858, COSV68692323; called by muse, mutect2, varscan2
- RFPL1 | c.186G>A p.K62= | Silent (SNP) | VAF 153/641 reads (24%) | called by muse, mutect2, varscan2
- RPS15 | c.51C>T p.Y17= | Silent (SNP) | VAF 119/549 reads (22%) | called by muse, mutect2, varscan2
- SLC13A3 | c.1311C>T p.F437= | Silent (SNP) | VAF 58/337 reads (17%) | catalogued as rs776497838, COSV51713345; called by muse, mutect2, varscan2
- SLC6A11 | c.882C>T p.S294= | Silent (SNP) | VAF 18/320 reads (6%) | catalogued as rs996788555, COSV54396591, COSV99594369; called by muse, mutect2
- SPATA31D1 | c.153G>A p.S51= | Silent (SNP) | VAF 94/426 reads (22%) | catalogued as rs774360466, COSV61195517; called by muse, mutect2, varscan2
- TNK1 | c.1650C>T p.S550= (on ENST00000576812 / NM_001251902.2; = p.S545= on NM_003985.5) | Silent (SNP) | VAF 165/850 reads (19%) | catalogued as rs1470337013; called by muse, mutect2, varscan2
- TTN | c.55893G>A p.P18631= (on ENST00000591111; = p.P11207= on NM_003319.4) | Silent (SNP) | VAF 249/446 reads (56%) | catalogued as rs727504529, COSV60052534; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF205 | c.954C>T p.S318= | Silent (SNP) | VAF 166/630 reads (26%) | called by muse, mutect2, varscan2
- ROCK1 | c.-181C>T | 5'UTR (SNP) | VAF 13/433 reads (3%) | called by muse, mutect2
